Somatic mutation profile of tumor specimen TCGA-SP-A6QI-01A (aliquot TCGA-SP-A6QI-01A-12D-A35I-08) from TCGA case TCGA-SP-A6QI, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 47.0 years (17,167 days).
Specimen TCGA-SP-A6QI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a164f9fe-cde0-4a95-ad7b-1f9aa4ab4ac6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-SP-A6QI-10A (Blood Derived Normal), aliquot TCGA-SP-A6QI-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e8d591dd-6149-4194-bca0-cb84441accbd

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PREB | c.787C>T p.R263* | Nonsense Mutation (SNP) | VAF 7/41 reads (17%) | catalogued as rs1298397838; called by muse, mutect2, varscan2
- COLGALT2 | c.866A>G p.Y289C | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TBXA2R | c.7C>T p.P3S | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARMT1 | c.1113G>A p.R371= | Silent (SNP) | VAF 18/79 reads (23%) | called by muse, mutect2, varscan2
